Surgical pathology report (de-identified scan), TCGA case TCGA-50-5930, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5930-01A (Primary Tumor).

[page 1 of 2]
ADDENDA:

Addendum

Immunohistochemical stains demonstrate that the tumor is strongly positive for cytokeratin 7 and negative for cytokeratin 20. These findings are consistent with the lung tumor being a primary lung lesion and not metastatic disease.

FINAL DIAGNOSIS:

- PART 1: LYMPH NODE, SUBCARINAL, EXCISION –
BENIGN LYMPH NODE, NEGATIVE FOR METASTATIC ADENOCARCINOMA.
- PART 2: LYMPH NODE, LEFT TRACHEAL-BRONCHIAL, EXCISION –
LYMPH NODE, NEGATIVE FOR METASTATIC ADENOCARCINOMA.
- PART 3: LYMPH NODE, TRACHEAL-BRONCHIAL, RIGHT, EXCISION –
LYMPH NODE, NEGATIVE FOR METASTATIC ADENOCARCINOMA.
- PART 4: LUNG, RIGHT UPPER LOBE, BIOPSY OF MASS –
POSITIVE FOR NON-SMALL CELL CARCINOMA.
- PART 5: LYMPH NODE, TRACHEAL-BRONCHIAL, EXCISION –
POSITIVE FOR METASTATIC ADENOCARCINOMA.
- PART 6: LUNG, RIGHT, PNEUMONECTOMY –
A. MODERATELY DIFFERENTIATED ADENOCARCINOMA, 3.9 CM, IN PART CLEAR-CELL TYPE.
B. TUMOR FOCALLY INVADES VISCERAL PLEURA BUT DOES NOT PENETRATE IT.
C. ANGIOLYMPHATIC INVASION IDENTIFIED.
D. SIX OF TWENTY-FIVE (6/25) LYMPH NODES POSITIVE FOR METASTATIC ADENOCARCINOMA.
E. NO PERINEURAL INVASION IDENTIFIED.
F. SURGICAL MARGINS OF RESECTION ARE FREE OF TUMOR.
G. PATHOLOGIC STAGE T2, N1, MX (see comment).
H. EMPHYSEMATOUS CHANGES.
I. SMOKER'S BRONCHIOLITIS.
- PART 7: LYMPH NODE, MAIN PA, EXCISION –
LYMPH NODE, NEGATIVE FOR METASTATIC ADENOCARCINOMA.
- PART 8: LYMPH NODE, MAIN PA, EXCISION –
LYMPH NODE, NEGATIVE FOR METASTATIC ADENOCARCINOMA.
- PART 9: LYMPH NODE, HILAR REGION, EXCISION –
LYMPH NODE, NEGATIVE FOR METASTATIC ADENOCARCINOMA.
- PART 10: LYMPH NODE, LEVEL 12, EXCISION –
LYMPH NODE, NEGATIVE FOR METASTATIC ADENOCARCINOMA.
- PART 11: LYMPH NODE, SUBCARINAL REGION, EXCISION –
LYMPH NODE, NEGATIVE FOR METASTATIC ADENOCARCINOMA.

COMMENT:

Within the submitted tissue, there is a 3.9 cm, moderately differentiated adenocarcinoma which in part is of clear-cell type. Based on the solitary nature of the neoplasm, we favor it being a primary lung tumor, however, immunohistochemical stains are being performed to rule out the possibility of metastatic disease. In total, seven lymph nodes are positive for metastatic carcinoma, six of these being from the hilus and one being a tracheal-bronchial lymph node. Since we are unsure what level the tracheal-bronchial lymph comes from, the pathologic stage is T2, N1, MX. Results of immunohistochemical stains will be reported in a separate addendum.

[page 2 of 2]
SYNOPTIC – PRIMARY LUNG TUMORS

A. Location: 3

1. RUL

2. RML

3. RLL

4. LLL

5. LUL

6. Bronchus intermedius

B. Procedure: 4

1. Wedge/Segmental

2. Lobectomy

3. Bilobectomy

4. Pneumonectomy

C. Size of tumor (maximum dimension): 3.9 cm.

D. Satellite nodules: 2

1. yes

2. no

E. Type: 3

1. Invasive squamous carcinoma

2. Basaloid squamous carcinoma

3. Invasive adenocarcinoma

4. Bronchioloalveolar carcinoma, nonmucinous type

5. Bronchioloalveolar carcinoma, mucinous type

6. Large cell carcinoma

7. Clear cell carcinoma

8. Giant cell carcinoma

9. Sarcomatoid carcinoma

10. Blastoma

11. Fetal type adenocarcinoma

12. Small cell carcinoma

13. Carcinoid

14. Atypical carcinoid

15. Sarcoma

16. Adenosquamous carcinoma

17. Mixed non-small cell carcinoma, NOS

18. Carcinosarcoma

19. Other

F. Architectural grade: 2

1. well

2. moderate

3. poor/undifferentiated

G. Nuclear grade: 2

1. Low

2. Intermediate

3. High

H. Central vs. peripheral origin: Not applicable

1. yes

2. no

I. Visceral pleural invasion through elastica: 1

1. yes

2. no

J. Parietal pleural invasion: 2

1. yes

2. no

K. Chest wall invasion (into skeletal muscle or soft tissue): 2

1. yes

2. no

L. Angiolymphatic invasion: 1

1. yes

2. no

M. Necrosis: 1

1. ≤50%

2. >50%

N. Surgical margins involved: 2

1. yes

2. no

O. Inflammatory (desmoplastic) reaction: 1

1. mild

2. moderate

3. severe

P. Hilar lymph node involvement: 1

1. yes

2. no

Q. If hilar lymph nodes involved, 6 positive / 25 examined = 2 / 25

R. Mediastinal nodes involved: 1

1. yes

2. no

3. not applicable

S. Mediastinal node group(s) involved: 2

1. Level 4R

4. Level 7R

7. Level 4L

10. Level 7L

2. Level 5R

5. Level 9R

8. Level 5L

11. Level 9L

3. Level 6R

6. Level 10R

9. Level 6L

12. Level 10L

T. Underlying disease(s): 1 / 4

1. Emphysema

4. Smokers bronchiolitis

7. Pneumoconiosis, NOS

2. Bronchiectasis

5. Asthma

8. Chronic interstitial pneumonia

3. Tumorlets

6. Parenchymal scar

U. TNM Stage: T 2 N 1 M X

Source: NCI Genomic Data Commons file d0bc9559-6d88-4c3e-99d3-070e2ccf012b (TCGA-50-5930.EBB21844-9982-40DA-972B-6F52941C5C4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).